Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A1EC, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A1EC-01A (Primary Tumor).

[page 1 of 4]
Carcinoma, hepatocellular, NOS 8170/3
Site Code: Liver C 22.0 1/19/11
lw

Patient Key:
Surgical date:

TISSUE DESCRIPTION:

A1 B1 B2 B3 B4 B5 B6 B7 B8 B9 B10 B11 B12 C1

Tissue from liver (segments V and VI--810 grams, 14.0 x 13.5 x 7.8 cm with gallbladder--8.8 x 2.2 x 1.3 cm), appendix (3.8 x 0.6 x 0.5 cm), retrocholedochal lymph node (2.0 x 1.5 x 1.2 cm)

DIAGNOSIS:

Liver, segments V and VI and gallbladder, resection: Grade 3 (of 4) hepatocellular carcinoma forming a 13.2 x 11.0 x 7.8 cm lobulated mass. Margins of resection are free by at least 0.7 cm. The gallbladder shows no diagnostic abnormality.

Appendix, appendectomy: Fibrous obliteration of the tip.

Lymph node, retrocholedochal, excision: One retrocholedochal lymph node, negative for tumor.

[page 2 of 4]
Patient Key:
Surgical date:

TISSUE DESCRIPTION:

A1 B1 B2 B3 B4 B5 B6 B7 B8 B9 B10 B11 B12 C1

Tissue from liver (segments V and VI--810 grams, 14.0 x 13.5 x 7.8 cm with gallbladder--8.8 x 2.2 x 1.3 cm), appendix (3.8 x 0.6 x 0.5 cm), retrocholedochal lymph node (2.0 x 1.5 x 1.2 cm)

DIAGNOSIS:

Liver, segments V and VI and gallbladder, resection: Grade 3 (of 4) hepatocellular carcinoma forming a 13.2 x 11.0 x 7.8 cm lobulated mass. Margins of resection are free by at least 0.7 cm. The gallbladder shows no diagnostic abnormality.

Appendix, appendectomy: Fibrous obliteration of the tip.

Lymph node, retrocholedochal, excision: One retrocholedochal lymph node, negative for tumor.

[page 3 of 4]
Liver • Digestive System CAP Approved

* Data elements *with asterisks* are *not required* for accreditation purposes for the Commission on Cancer. These elements may be clinically important, but are not yet validated or regularly used in patient management. Alternatively, the necessary data may not be available to the pathologist at the time of pathologic assessment of this specimen.

LIVER: ResectionPatient name: *(to be de-identified)*

Surgical pathology number:

MACROSCOPIC**Specimen Type**

- ☒ Right lobectomy
- ☐ Extended right lobectomy
- ☐ Medial segmentectomy
- ☐ Left lateral segmentectomy
- ☐ Total left lobectomy
- ☐ Explanted liver
- ☐ Other (specify): _____
- ☐ Not specified

Focality

- ☒ Solitary (specify location): segment 7
- ☐ Multiple (specify location): _____

Tumor SizeGreatest dimension: 13.2 cm*Additional dimensions: 4.2 x 2.8 cm☐ Cannot be determined (see Comment)**MICROSCOPIC****Histologic Type**

- ☒ Hepatocellular carcinoma
- ☐ Fibrolamellar hepatocellular carcinoma variant (specify): _____
- ☐ Combined hepatocellular and cholangiocarcinoma
- ☐ Cholangiocarcinoma, intrahepatic
- ☐ Bile duct cystadenocarcinoma
- ☐ Undifferentiated carcinoma
- ☐ Other (specify): _____
- ☐ Carcinoma, type cannot be determined

Histologic Grade

- ☐ Not applicable
- ☐ GX: Cannot be assessed
- ☐ GI: Well differentiated
- ☐ GII: Moderately differentiated
- ☒ GIII: Poorly differentiated
- ☐ GIV: Undifferentiated/anaplastic
- ☐ Other (specify): _____

[page 4 of 4]
Pathologic Staging (pTNM)**Primary Tumor (pT)**

- ☐ pTX: Cannot be assessed
☐ pT0: No evidence of primary tumor
☒ pT1: Solitary tumor with no vascular invasion
☐ pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm
☐ pT3: Multiple tumors more than 5 cm or tumor involving a major branch of the portal or hepatic vein(s)
☐ pT4: Tumor(s) with direct invasion of adjacent organs other than the gallbladder or perforation of visceral peritoneum

Regional Lymph Nodes (pN)

- ☐ pNX: Cannot be assessed
☒ pN0: No regional lymph node metastasis
☐ pN1: Regional lymph node metastasis

Specify: Number examined: 1

Number involved: 0

Distant Metastasis (pM)

- ☒ pMX: Cannot be assessed
☐ pM1: Distant metastasis

*Specify site(s), if known: _____

Margins (check all that apply)**Parenchymal Margin**

- ☐ Cannot be assessed
☒ Uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 1.5 mm
Specify margin: _____

☐ Involved by invasive carcinoma

Bile Duct Margin (Cholangiocarcinoma Only)

- ☒ Cannot be assessed
☐ Uninvolved by invasive carcinoma
* ☐ Carcinoma in situ absent
* ☐ Carcinoma in situ present
☐ Involved by invasive carcinoma

Other Margin

- Specify margin: _____
☐ Cannot be assessed
☐ Uninvolved by invasive carcinoma
☐ Involved by invasive carcinoma

***Venous (Large Vessel) Invasion (V)**

- * ☐ Absent
* ☐ Present
* ☒ Indeterminate

***Additional Pathologic Findings (check all that apply)**

- * ☒ None identified
* ☐ Hepatocellular dysplasia
* ☐ Ductal dysplasia
* ☐ Cirrhosis/fibrosis
* ☐ Iron overload
* ☐ Hepatitis (specify type): _____
* ☐ Other (specify): _____

Source: NCI Genomic Data Commons file ceae9896-648b-4824-b2aa-b764cbf3f609 (TCGA-DD-A1EC.7CF5361C-34F3-496F-A7FC-AF4E9F2BD859.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).